Somatic mutation profile of tumor specimen TCGA-ZB-A96Q-01A (aliquot TCGA-ZB-A96Q-01A-11D-A428-09) from TCGA case TCGA-ZB-A96Q, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 50.0 years (18,249 days).
Specimen TCGA-ZB-A96Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bba17a37-1d47-4f59-9c61-30d81567c5e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96Q-10A (Blood Derived Normal), aliquot TCGA-ZB-A96Q-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0307b7a0-17d1-4a14-aad2-1775f07462a7

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 58/431 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- NIPBL | c.7501C>T p.R2501W | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs1324046982, COSV56966921; called by muse, mutect2, varscan2
- NKX2-3 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as COSV60728504; called by muse, mutect2
- ADAMTS9 | c.3381C>A p.Y1127* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.3823_3824insG p.K1275Rfs*18 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | called by mutect2, pindel*, varscan2*
- ESCO2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGA | c.1774G>A p.G592R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ADGRG4 | c.1755T>C p.T585= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV54951227; called by muse, mutect2, varscan2
- SCN2A | c.2340C>T p.H780= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
